Somatic mutation profile of tumor specimen 69d552be-7cb2-4bb4-b602-a27b3e (aliquot 69d552be-7cb2-4bb4-b602-a27b3e_D6) from CPTAC case 04OV045, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 69d552be-7cb2-4bb4-b602-a27b3e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c12eec06-12f5-4523-b6cb-42a48d32a73d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 67019441-8b3d-4bda-bdf4-21a297 (Blood Derived Normal), aliquot 67019441-8b3d-4bda-bdf4-21a297_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87fa7d76-45f0-4271-80fd-0ecc91295a3d

The open-access MAF lists 100 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 9, 3'UTR 6, RNA 5, Splice Region 2, Splice Site 2, 5'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 172/340 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSI | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 139/478 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201427501; called by muse, mutect2, varscan2
- BLOC1S5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99789574; called by muse, mutect2, varscan2
- CYP2C9 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs748042778; called by muse, mutect2, varscan2
- DMRTA2 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68672418; called by muse, mutect2
- KIF7 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1374666466; called by muse, mutect2, varscan2
- LZTR1 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs1237504479; called by muse, mutect2
- MSX1 | c.902A>G p.H301R | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776499548; called by muse, mutect2, varscan2
- MYO7B | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs766688222, COSV101268022; called by muse, mutect2, varscan2
- NAV3 | c.4315G>C p.E1439Q | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs747945999; called by muse, mutect2, varscan2
- NDST4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52121427; called by muse, mutect2, varscan2
- OR5I1 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs913931606, COSV56885185; called by muse, mutect2, varscan2
- PDZD2 | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.408); catalogued as rs753566078; called by muse, mutect2
- RGPD4 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100736277, COSV61748523; called by muse, mutect2
- RPL8 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 202/800 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV52800207; called by muse, mutect2, varscan2
- RXRA | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62683548; called by mutect2, varscan2
- SCN7A | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV69271073; called by muse, mutect2, varscan2
- SEMA6C | c.2123C>A p.P708Q | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as rs1268164506; called by muse, mutect2, varscan2
- TAS2R43 | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV67860951; called by muse, mutect2, varscan2
- ADAM15 | c.2424+4A>G | Splice Region (SNP) | VAF 35/106 reads (33%) | called by muse, mutect2, varscan2
- ADPRH | c.170C>G p.T57R | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALAS2 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 112/348 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, varscan2
- CCDC162P | n.5575G>C | Splice Region (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- CCDC87 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- COL6A6 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTTNBP2 | c.3743C>T p.T1248I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL4B | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- DENND1A | c.2065G>A p.V689M | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ECE2 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERC2 | c.744C>G p.N248K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- FBXW5 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 39/377 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMNL2 | c.915A>T p.E305D | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.632); called by mutect2, varscan2
- FOLH1 | c.1013_1019+22del p.X338_splice | Splice Site (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- HUWE1 | c.145-1G>T p.X49_splice | Splice Site (SNP) | VAF 62/368 reads (17%) | called by muse, mutect2, varscan2
- INSM2 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAKMIP2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KAT6B | c.5285G>C p.S1762T | Missense Mutation (SNP) | VAF 147/431 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL34 | c.1307G>C p.G436A | Missense Mutation (SNP) | VAF 120/870 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KTN1 | c.1956G>C p.Q652H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K15 | c.3134T>G p.V1045G | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MMP3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NEK10 | c.2050A>T p.S684C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHS | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, varscan2
- NRCAM | c.2519C>T p.S840F (on ENST00000379028 / NM_001371124.1; = p.S824F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D14 | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGA8 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- RASA1 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SGPP2 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SIVA1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.185); called by muse, mutect2
- SLAMF6 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX32 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- STC1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STK32B | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TDRD15 | c.2938T>A p.F980I | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM67 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPA1 | c.1661T>A p.F554Y | Missense Mutation (SNP) | VAF 284/588 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TSC22D3 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VSTM4 | c.384_407del p.V129_R136del | In Frame Del (DEL) | VAF 95/300 reads (32%) | called by mutect2, pindel, varscan2
- WFIKKN2 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- ABCC9 | c.729T>A p.I243= | Silent (SNP) | VAF 130/507 reads (26%) | catalogued as COSV99684867; called by muse, mutect2, varscan2
- ADGRA2 | c.2031C>A p.P677= | Silent (SNP) | VAF 102/227 reads (45%) | catalogued as COSV59443432; called by muse, mutect2, varscan2
- BATF2 | c.361C>T p.L121= | Silent (SNP) | VAF 21/214 reads (10%) | catalogued as rs777853701; called by muse, mutect2, varscan2
- CDC42BPG | c.3210C>T p.D1070= | Silent (SNP) | VAF 136/392 reads (35%) | catalogued as rs545181881; called by muse, mutect2, varscan2
- CMC4 | c.147C>G p.V49= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV62898972; called by muse, mutect2, varscan2
- CTBP2 | c.369G>T p.V123= | Silent (SNP) | VAF 137/420 reads (33%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.396G>C p.V132= | Silent (SNP) | VAF 79/226 reads (35%) | called by muse, mutect2, varscan2
- GLIS3 | c.159G>A p.A53= | Silent (SNP) | VAF 67/195 reads (34%) | catalogued as rs770666979; called by muse, mutect2, varscan2
- GTF2E1 | c.1233G>C p.R411= | Silent (SNP) | VAF 31/594 reads (5%) | catalogued as COSV99382078; called by muse, mutect2
- HIP1 | c.2814C>G p.A938= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100416873; called by muse, mutect2, varscan2
- MAPK8 | c.396C>G p.L132= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- MGAT4B | c.1447C>T p.L483= | Silent (SNP) | VAF 26/373 reads (7%) | called by muse, mutect2
- NDUFS1 | c.1614G>T p.R538= | Silent (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- PROB1 | c.2394G>T p.S798= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SELENBP1 | c.1308G>C p.L436= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- SLC36A1 | c.1192C>T p.L398= | Silent (SNP) | VAF 102/369 reads (28%) | catalogued as rs1296430851; called by muse, mutect2, varscan2
- TMEM108 | c.909C>T p.A303= | Silent (SNP) | VAF 125/526 reads (24%) | called by muse, mutect2, varscan2
- TNPO2 | c.2682C>T p.F894= (on ENST00000425528 / NM_001382240.1; = p.F884= on NM_013433.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- UNC119 | c.633G>A p.P211= | Silent (SNP) | VAF 232/490 reads (47%) | catalogued as rs560119422, COSV56379091; called by muse, mutect2, varscan2
- AP000842.1 | n.349T>A | RNA (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- APOO | c.*30-3263A>G | Intron (SNP) | VAF 105/366 reads (29%) | called by muse, mutect2, varscan2
- ASB4 | c.978+58_978+84del | Intron (DEL) | VAF 38/149 reads (26%) | called by mutect2, pindel
- CKAP5 | c.4027+157A>T | Intron (SNP) | VAF 38/157 reads (24%) | called by muse, mutect2, varscan2
- CRACR2B | c.953+21G>C | Intron (SNP) | VAF 73/142 reads (51%) | called by muse, mutect2, varscan2
- GORAB | c.*1044C>G | 3'UTR (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- LIG1 | c.1088-64G>A | Intron (SNP) | VAF 14/213 reads (7%) | catalogued as rs946454395; called by muse, mutect2
- LINC01517 | n.201+7_201+8insTTTCAGGTTTTTT | RNA (INS) | VAF 14/102 reads (14%) | called by mutect2, varscan2
- LSM4 | c.4-27A>G | Intron (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- MAP7D1 | c.2131-12G>A | Intron (SNP) | VAF 72/130 reads (55%) | called by muse, mutect2, varscan2
- MIR3150B | chr8:95075637 T>C | 5'Flank (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- OPCML | c.937+924G>T | Intron (SNP) | VAF 56/316 reads (18%) | called by mutect2, varscan2
- OR2U1P | n.307G>T | RNA (SNP) | VAF 49/228 reads (21%) | called by muse, mutect2, varscan2
- POLR2G | c.*25C>G | 3'UTR (SNP) | VAF 51/163 reads (31%) | called by muse, mutect2, varscan2
- SCOC | c.181+375C>G | Intron (SNP) | VAF 89/319 reads (28%) | called by muse, mutect2, varscan2
- SHLD2P3 | n.2601G>C | RNA (SNP) | VAF 32/182 reads (18%) | catalogued as rs1418550016; called by muse, mutect2, varscan2
- SLC7A5P1 | n.357C>G | RNA (SNP) | VAF 61/622 reads (10%) | called by muse, mutect2, varscan2
- SLURP1 | c.*50G>C | 3'UTR (SNP) | VAF 40/878 reads (5%) | catalogued as rs763644878, COSV99872945; called by muse, mutect2
- SMARCAD1 | c.*679G>A | 3'UTR (SNP) | VAF 127/584 reads (22%) | called by muse, mutect2, varscan2
- STK17A | c.-65G>C | 5'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- TMEM179 | c.*2037C>G | 3'UTR (SNP) | VAF 104/157 reads (66%) | called by mutect2, varscan2
- UGT1A6 | c.*11_*12del | 3'UTR (DEL) | VAF 51/180 reads (28%) | called by mutect2, pindel*, varscan2*
